Gene-level copy-number profile of tumor specimen TCGA-K7-AAU7-01A from TCGA case TCGA-K7-AAU7, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Combined hepatocellular carcinoma and cholangiocarcinoma; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 61.5 years (22,476 days).
Specimen TCGA-K7-AAU7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.5979aa23-0800-4737-b2bf-1563dff743c7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-K7-AAU7-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f93d1c77-441a-4c11-958f-fe7d5c47ddda

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 6,869; copy number 4: 48,046; copy number 5: 52; copy number 6: 3,028; copy number 8: 33; copy number 10: 16; copy number 11: 764; copy number 12: 215; copy number 13: 555; copy number 15: 20; copy number 18: 78; copy number 27: 25; copy number 31: 33; copy number 36: 19; copy number 38: 12; copy number 40: 24; copy number 68: 29.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-K7-AAU7-01A-11D-A381-01): tumor purity 0.53, ploidy 2.13, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,790 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:179,455,415–181,342,213, 94 genes, copy number 10–18 (broad region; genes not listed).
- chr8:46,028,804–145,066,685, 1,534 genes, copy number 11–13 (broad region; genes not listed).
- chr12:630,858–2,697,950, 33 genes, copy number 31 (within-gene range 2–31): NINJ2-AS1, LINC02455, WNK1, RNU4ATAC16P, AC004765.1, RAD52, AC004803.1, ERC1, HTR1DP1, AC004672.1, AC004672.2, LINC00942, WNT5B, FBXL14, MIR3649, ADIPOR2, AC005183.1, AC005343.4, RPS4XP14, CACNA2D4, AC005343.7, LRTM2, AC005342.2, LINC00940, DCP1B, CACNA1C, AC005342.1, CACNA1C-IT1, CACNA1C-IT2, AC005344.1, CACNA1C-AS4, CACNA1C-IT3, AC005293.1.
- chr12:24,949,163–26,833,194, 41 genes, copy number 38–68 (within-gene range 2–68): AC026310.1, BRI3P2, C12orf77, IRAG2, CENPUP2, AC023510.1, AC023510.2, CFAP94, ETFRF1, KRAS, AC092794.1, AC092794.2, AC087239.1, RNU4-67P, AC092451.1, LMNTD1, AC092451.2, FAM133GP, TUBB4BP1, AC022367.1, RN7SKP262, AC019209.3, TDGP1, AC019209.2, MIR4302, AC019209.1, RASSF8-AS1, RASSF8, BHLHE41, SSPN, AC022509.3, AC022509.5, AC022509.2, AC022509.1, AC022509.4, AC055720.1, AC055720.3, AC024145.1, ITPR2, AC055720.2, RNA5SP354.
- chr12:27,243,968–27,325,959, 1 gene, copy number 36: STK38L.
- chr12:27,523,431–27,695,564, 1 gene, copy number 40 (within-gene range 4–40): PPFIBP1.
- chr12:27,592,461–31,369,301, 73 genes, copy number 15–40 (broad region; genes not listed).
- chr12:31,396,390–31,396,501, 1 gene, copy number 36: RNU6-618P.
- chr12:31,876,969–32,107,528, 11 genes, copy number 27: LINC02422, AC023050.4, AC023050.1, RPL12P32, AC023050.5, RESF1, AC016957.2, AC016957.1, AC048344.2, AC048344.3, AC048344.1.
- chr12:32,109,076–32,109,602, 1 gene, copy number 27: AC048344.4.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
